Gene-level copy-number profile of tumor specimen TCGA-G3-A25X-01A from TCGA case TCGA-G3-A25X, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.9 years (26,988 days).
Specimen TCGA-G3-A25X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7cda17f7-dd19-478a-a819-952d1a4c6f33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-A25X-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/de9a93ac-ed2f-48ac-9406-f122155d2730

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 9,518; copy number 2: 17,294; copy number 3: 21,851; copy number 4: 6,426; copy number 5: 2,060; copy number 6: 923; copy number 7: 1,113; copy number 8: 296; copy number 9: 79; copy number 10: 1; copy number 11: 155; copy number 18: 64.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:163,524,298–164,384,050, 1 gene (within-gene range 0–11): MARCHF1.
- chr4:163,828,800–165,498,547, 37 genes (within-gene range 0–11): RN7SKP105, YWHAQP4, AC105250.1, ANP32C, AC074198.1, RNU6-284P, CHORDC1P3, SMIM31, RNU6-668P, APELA, TRIM60P14, AC106872.3, AC106872.12, FAM218BP, AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P, TMEM192, KLHL2, RNU4-87P, GK3P, MSMO1, CPE, MIR578, HADHAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,708 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–163,321,791, 878 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:172,659,103–175,922,145, 61 genes, copy number 7 (broad region; genes not listed).
- chr1:175,968,398–175,968,540, 1 gene, copy number 7: SCARNA3.
- chr1:190,097,658–205,632,011, 281 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr4:133,871,246–163,520,539, 416 genes, copy number 8–18 (within-gene range 3–18) (broad region; genes not listed).
- chr4:163,529,771–163,530,697, 1 gene, copy number 11: AC093788.1.
- chr4:165,517,255–173,041,559, 70 genes, copy number 11 (within-gene range 1–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,518. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
